Somatic mutation profile of tumor specimen 0DSCP4 from CCDI case PBCHPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,414 days).
Specimen 0DSCP4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91a71622-4095-49b4-8cdf-5d8341145f9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSCOU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19bcd61d-229d-4f88-8967-30e6219b8720

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Silent 1, Nonsense Mutation 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STARD3NL | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 299/1027 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1286234851; called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 29/1092 reads (3%) | called by muse, mutect2
- HACE1 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 38/1037 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.22); called by muse, mutect2
- USP25 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 856/1461 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO4 | c.765T>G p.V255= | Silent (SNP) | VAF 411/747 reads (55%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 40/390 reads (10%) | called by muse, varscan2
- KRT25 | c.-18C>T | 5'UTR (SNP) | VAF 50/122 reads (41%) | catalogued as rs1313370541, COSV56445460; called by muse, mutect2, varscan2
- MUC16 | c.*86G>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | catalogued as rs1050742798, COSV101109888; called by mutect2, varscan2
- RAI1 | c.5660-85G>C | Intron (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2
